Surgical pathology report (de-identified scan), TCGA case TCGA-XU-A92Q, project TCGA-THYM (Thymoma), tissue source site University Health Network, specimen TCGA-XU-A92Q-01A (Primary Tumor).

[page 1 of 3]
Patient Name:

MRN:

DOB:

Gender:M

Service:

Visit #:

Location:

Facility:

Collected:

Resulted:

Ordering MD:

Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED

1. Thymus: thymus gland - stitch on rt upper pole
2. Lymph node: Left Periphrenic node

*ICD-3
Thymoma, type A, malignant 8581/3
Site Thymus C87.9
JCO 4/2/14*

DIAGNOSIS

1. Thymectomy:

- Two separate thymomas:
- WHO type AB thymoma, right side, 5.2 cm in greatest diameter.
- Tumor shows extension outside fibrous capsule into peritumoral adipose tissue.
- Adjacent painted margins negative for tumor.
- WHO type A thymoma, left side, 5 cm in greatest diameter.
- Tumor completely encapsulated, no invasion into or outside capsule.
- Adjacent painted margins negative for tumor.

2. Left periphrenic node biopsy:

- Normal lymph node.

SYNOPTIC DATA

Specimen Type:

Specimen Size:

Tumor Site:

Tumor Size:

Histologic Type:

Pathologic Staging:
invasion

Regional Lymph Nodes:
metastasis

Distant Metastasis:

Thoracotomy

Greatest dimension: 23.5 cm

Additional dimensions: 13.5 x 3.3 cm

Thymus

Greatest dimension: 5.2 cm

Additional dimensions: 3.5 x 2.5 cm

Type AB thymoma (mixed)

Stage IIa: Microscopic transcapsular

pN0: No regional lymph node

Cannot be assessed

Status: complete

Page: 1 of 3

[page 2 of 3]
Patient Name:

MRN: .

DOB:

Gender:M

Service:

Visit #:

Location:

Facility:

Collected

Resulted:

Ordering MD:

Margins:

Margins uninvolved by tumor

Distance of tumor from closest

margin: 5 mm

Invasion of Pulmonary Parenchyma: Absent

Pleural Invasion: Absent

Vascular (Small/Large Vessel) Invasion: Absent

Specimen Type:

Thoracotomy

Specimen Size:

Greatest dimension: 23.5 cm

Additional dimensions: 13.5 x 3.3 cm

Tumor Site:

Thymus

Tumor Size:

Greatest dimension: 5 cm

Additional dimensions: 4 x 3.1 cm

Histologic Type:

medullary)

Type A thymoma (spindle cell,

Pathologic Staging:

Stage I: Grossly and microscopically

encapsulated

Regional Lymph Nodes:

pN0: No regional lymph node

metastasis

Distant Metastasis:

Cannot be assessed

Margins:

Margins uninvolved by tumor

Distance of tumor from closest

margin: 5 mm

Invasion of Pulmonary Parenchyma: Absent

Pleural Invasion: Absent

Vascular (Small/Large Vessel) Invasion: Absent

← * Per TSS,
this tumor
sent for TCGA.

COMMENT

The left sided type A thymoma is composed of pure spindle tumor cells. The histological appearance of this tumor is identical to that seen in a previous needle core biopsy.

The right-sided type AB thymoma shows mostly lymphocyte rich areas that contain larger cells with abundant cytoplasm and vesicular nuclei and inconspicuous nucleoli. More importantly these lymphocyte rich areas are intersected by bands of more spindle-appearing cells with oval nuclei and bland nuclei. There are also small islands of pure spindle type-A like tumor nodules.

Status: complete

Page: 2 of 3

[page 3 of 3]
Patient Name

MRN:

DOB:

Gender: M

Ordering MD:

Service:

Visit #:

Location:

Facility:

Collected:

Resulted:

Both tumors appear completely excised.

ELECTRONICALLY VERIFIED BY: I

CLINICAL HISTORY

Thymoma

GROSS DESCRIPTION

1. The specimen is labeled with the patient's name and as "thymus gland stitch on right upper pole". It consists of a thymus gland with suture at upper pole and having an overall dimension of 23.5 SI x 13.5 ML x 3.3 AP

cm. It is painted with silver nitrate. On the mid right full a firm tan well circumscribed lobular nodule measures 3.5 x 5.2 x 2.5 cm and a second nodule also well-circumscribed and tan and homogeneous measures 4 x 5 x 3.1 cm. The remaining tissue appears grossly unremarkable. 4 pieces of 2 tumor and 4 pieces of thymus taken for tissue bank. Representative sections submitted.

1A-1F tumor from the right lobe

1G-1J normal section from the right lobe

1K midsection

1L-1O tumor left lobe

1P-1T normal section to left lobe

2. The specimen container, labeled with the patient's name and as "left periphrenic node", contains a piece of fibrofatty tissue measuring 5 x 2.5 x 1.2 cm, received in 10% NBF. This contains 2 lymph node measuring from 0.3 x 0.3 x 0.1 to 0.4 x 0.2 x 0.2 cm.

2A 2 nodes

Status: complete

Source: NCI Genomic Data Commons file f6fdb553-8a90-41bc-bc71-9e05c16d2a34 (TCGA-XU-A92Q.933D8D0D-10F0-40F0-8085-0DAEFF7738A5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).